Somatic mutation profile of tumor specimen TCGA-D3-A2J9-06A (aliquot TCGA-D3-A2J9-06A-11D-A196-08) from TCGA case TCGA-D3-A2J9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.3 years (27,508 days).
Specimen TCGA-D3-A2J9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9d2fad1-d643-4ea2-8baa-dd3d887ffa40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2J9-10A (Blood Derived Normal), aliquot TCGA-D3-A2J9-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ca00541-3399-45ff-a108-cc4680cb1719

The open-access MAF lists 68 somatic variants for this specimen: 39 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 36, Silent 29, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV56257487; called by muse, mutect2, varscan2
- ATP2C2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.875); catalogued as COSV52295894, COSV52297365; called by muse, mutect2, varscan2
- C1QTNF2 | c.470G>A p.G157E (on ENST00000393975; = p.G112E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1029022150, COSV67432703; called by muse, mutect2, varscan2
- CADPS2 | c.3861G>A p.M1287I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV57363196; called by muse, mutect2
- CARD11 | c.2508C>T p.S836= | Splice Region (SNP) | VAF 12/104 reads (12%) | catalogued as COSV62755239; called by muse, mutect2
- CEMIP | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV54992447; called by muse, mutect2, varscan2
- CTSA | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509877; called by muse, mutect2
- EDN1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761581288, COSV65080724, COSV65080801; called by muse, mutect2, varscan2
- FAM117B | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100288154, COSV57418982; called by muse, mutect2
- FBP1 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV64689316; called by muse, mutect2, varscan2
- GALNT17 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.709); catalogued as rs866308070, COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- HDAC11 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55473283; called by muse, mutect2
- HTR7 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV53286504; called by muse, mutect2, varscan2
- IFNA21 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs772979626, COSV66518414; called by mutect2, varscan2
- ITIH2 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV64433103; called by muse, mutect2, varscan2
- KATNB1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as rs1271670447, COSV65550242; called by muse, mutect2, varscan2
- KDM2B | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65640725; called by muse, mutect2, varscan2
- LPCAT1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52037420; called by muse, mutect2, varscan2
- LRIT2 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs947932172, COSV60562125; called by muse, mutect2
- MCM10 | c.1187A>T p.N396I (on ENST00000484800 / NM_182751.3; = p.N395I on NM_018518.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66334355; called by muse, mutect2, varscan2
- NPS | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV67690576; called by muse, mutect2, varscan2
- OR1A2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV67936414; called by muse, mutect2, varscan2
- PER2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54523590, COSV54527240; called by muse, mutect2
- PVALB | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.229); catalogued as rs538517587, COSV53412372; called by muse, mutect2, varscan2
- SETD2 | c.4885C>T p.H1629Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57431577; called by muse, mutect2, varscan2
- SLC2A12 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs571027180, COSV51599968; called by mutect2, varscan2
- SLC4A1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs748087778, COSV52259961; called by mutect2, varscan2
- SQOR | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as rs1453700860, COSV52941825; called by muse, mutect2, varscan2
- SRSF9 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57584532; called by muse, mutect2, varscan2
- SYN1 | c.864C>A p.F288L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV55981691; called by muse, mutect2, varscan2
- SYN2 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs749073807, COSV70285313; called by muse, mutect2
- TBP | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.365); catalogued as COSV57831966; called by muse, mutect2, varscan2
- THOC2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55545744; called by muse, mutect2, varscan2
- TSKS | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs867919180, COSV55874937, COSV99883470; called by muse, mutect2
- XIRP1 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs868078577, COSV61138459; called by muse, mutect2, varscan2
- ZBED9 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs866308071, COSV71729246; called by muse, mutect2
- ZMYM2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV67033282; called by muse, mutect2, varscan2
- GABPB1 | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- IGLV1-47 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- AAR2 | c.969C>T p.F323= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs775133590, COSV57923943, COSV57925041; called by muse, mutect2, varscan2
- AMBN | c.486G>A p.L162= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1364866896, COSV59826086; called by muse, mutect2, varscan2
- CAPN10 | c.783C>T p.I261= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV54376542; called by muse, mutect2, varscan2
- CCKBR | c.1251C>T p.P417= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV58101358, COSV58103429; called by muse, mutect2, varscan2
- CIT | c.1164T>C p.F388= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV55868403; called by muse, mutect2
- CRYBA4 | c.435C>T p.H145= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV61321952; called by muse, mutect2, varscan2
- CSE1L | c.2011C>T p.L671= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV53701816; called by muse, mutect2, varscan2
- CYP1A1 | c.1411C>T p.L471= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV65697171; called by muse, mutect2, varscan2
- FGR | c.885G>A p.P295= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV64969489; called by muse, mutect2, varscan2
- GCC1 | c.1047G>A p.E349= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV58461860, COSV58462537; called by muse, mutect2, varscan2
- HEPH | c.924C>T p.F308= (on ENST00000343002; = p.F41= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57961589; called by mutect2, varscan2
- HSPG2 | c.11490C>T p.I3830= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs377549147, COSV65933131; called by muse, mutect2, varscan2
- MDN1 | c.15327C>T p.S5109= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV65521467; called by mutect2, varscan2
- MICALL2 | c.2643C>T p.L881= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV52514796; called by muse, varscan2
- PAPPA2 | c.2964G>A p.L988= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV62797347; called by muse, mutect2, varscan2
- PAQR8 | c.552C>T p.A184= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as rs770103133, COSV62442539; called by muse, mutect2, varscan2
- PCDH8 | c.2262C>T p.I754= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs1466304483, COSV58810607; called by muse, mutect2
- PCDHAC1 | c.2265C>T p.L755= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV53848818; called by muse, mutect2, varscan2
- RARG | c.30G>A p.A10= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs756249363, COSV59532202; called by mutect2, varscan2
- RPS3 | c.573C>T p.P191= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV53704714; called by muse, mutect2, varscan2
- SHBG | c.681C>T p.L227= | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as rs759700153, COSV52646778; called by muse, mutect2
- SPOCD1 | c.171G>A p.R57= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57096305; called by muse, varscan2
- THRA | c.138C>T p.Y46= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV52842918; called by muse, mutect2
- TNR | c.2673C>T p.F891= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs760178073, COSV54882799, COSV54885463; called by mutect2, varscan2
- TRIM39 | c.1107C>T p.L369= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV64955341; called by muse, mutect2, varscan2
- UBE3C | c.1231C>T p.L411= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs143608582; called by muse, mutect2
- UNC5B | c.2586C>T p.I862= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV58977107; called by muse, mutect2
- WDR72 | c.1020T>A p.L340= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV64741733, COSV64746537; called by muse, varscan2
- ZNF217 | c.807C>T p.F269= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as COSV56596921; called by muse, mutect2, varscan2
